Surgical pathology report (de-identified scan), TCGA case TCGA-EQ-A4SO, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-EQ-A4SO-01A (Primary Tumor).

[page 1 of 3]
Final Surgical Pathology Report

1CD-0-3

Procedure:

Adenocarcinoma, intestinal type 8144/3

Diagnosis

Site: Stomach, antrum C16.3

A. Peritoneum, lesser sac, biopsy:

Negative for malignancy, benign fibroadipose tissue

B. Omentum, excision:

Negative for malignancy, benign omental fat

juw
10/26/12

C. Gallbladder, excision:

Benign gallbladder with mild chronic inflammation and fatty change
No malignancy identified

D. Head of pancreas, duodenum and bile duct and gastric antrum,
partial gastrectomy and pancreatectomy:
Gastric Adenocarcinoma, moderately differentiated, invasive into
pancreas (pT4b)

Metastatic adenocarcinoma identified in one peripancreatic lymph node
(overall 1 of 20 lymph nodes positive for metastatic tumor) (pN1)

Lymphatic and Venous space invasion identified

Resection margins are negative for tumor

Microscopic Description:

Microscopic examination performed.

A.-C. Microscopic examination reveals benign tissue

D. Microscopic examination of the gastrectomy with attached head of
pancreas, duodenum and bile duct as summarized in the gastric carcinoma
template below:

Histologic type: Adenocarcinoma, intestinal type

Histologic grade: Moderately differentiated

Tumor size: 4.8 x 4.5 x 3 CM

Primary tumor (pT): Tumor invades through the greater curvature into
the pancreas (pT4b)

Proximal margin: Negative for tumor

Distal margin: Negative for tumor

Radial margin: Negative for tumor, including pancreatic neck and
uncinate margins

Distance of tumor from closest margin: 3 mm from the free radial
surface in the area of the apparent "bile duct resection margin". This
is probably not a true anatomic margin given the gallbladder resection
but is striking histologic finding.. The closest apparent true radial
margin is 1.5 cm from pancreatic neck margin. Clinical correlation is
recommended.

Vascular invasion: Lymphatic space invasion is identified best seen in
block D3. A large vein is identified with significant tumor in block
D7

Regional lymph nodes (pN): One peripancreatic node is identified with
positive tumor. The lymph node measures 1.5 cm in greatest dimension
block D18. Overall lymph node count is 1 of 20 (pN1)

Distant metastasis (pM): Not applicable pMX

Other findings: There is background moderate chronic gastritis and some
fundic gland polyps are identified. A Helicobacter pylori
immunohistochemical stain was evaluated of blocks D. 14 and was
negative the duodenal mucosa is fairly unremarkable and the duodenal
papilla was negative for tumor.

[page 2 of 3]
[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Specimen

- A. Peritoneum lesser sac, biopsy
- B. Omentum
- C. Gallbladder
- D. Head of pancreas, duodenum and bile duct and antral cancer, long neck, short uncinate

Clinical Information

Gastric carcinoma

Intraoperative Consultation

- A. Peritoneum lesser sac, biopsy: Benign fibroadipose tissue.

Gross Description

A. Received fresh for frozen section labeled "peritoneum lesser sac" is a 0.6 x 0.4 x 0.2 cm piece tan to pink soft tissue entirely frozen as frozen section AFS 1.

B. Received fresh labeled "omentum" is a 24.5 x 13.0 x 5.5 cm are shown of soft, lobulated tan gold adipose tissue in keeping with omentum. No discrete mass lesion or abnormality is identified.

C. Received fresh labeled "gallbladder" is an intact, 8.5 x 4.5 x 4.1 cm gallbladder with attached 1 cm cystic duct. The lumen contains a copious amount of viscid dark green bile. No choleliths are present. The mucosa is velvety pale yellow green and the wall measures up to 0.3 cm. Received separately within the specimen container is an irregular 3.3 x 1.4 x 0.4 cm fragment of soft tan-pink-gold fibrofatty tissue.

Summary: 1- cystic duct margin and gallbladder neck; 2- body and fundus, 3 - additional tissue fragment

D. Received fresh labeled "head of pancreas, duodenum and bile duct and antral cancer" is a previously unopened portion of distal stomach measuring 15 cm along the lesser curvature, 24 cm along the greater curvature, and 3.8 cm from anterior to posterior, with attached 30 cm segment of proximal small bowel with associated 12.0 x 5.8 x 4.0 cm portion of pancreatic tissue. A moderate amount of adipose tissue is present along the greater and lesser curvature of the portion of stomach. The proximal gastric margin measures 21 cm in circumference and the distal duodenal margin measures 5 cm in circumference. A long suture, designating the "neck" of the pancreas is present in the area is subsequently inked orange. The region of the uncinate, designated by a short suture, is inked green. The remaining surface of the pancreatic tissue is inked blue. A portion of gastric tissue is opened along the greater curvature to reveal a nearly circumferential, 4.8 x 4.5 cm rubbery tan white tumor mass at the gastroduodenal junction. The common bile duct is probe patent to the duodenal lumen. The gastric lesion has a maximal thickness of 3 cm on sectioning, extending to abut the proximal ductal structure within 0.3 cm and extending to the inked free radial surface to within 0.1 cm (see contiguous sections blocks 3 through 5). The tumor is greater than 2.5 cm from the pancreatic uncinate margin and is 1.5 cm from the pancreatic neck margin (see blocks 6 and 7 respectively). The remaining pancreatic parenchyma is lobulated tan-yellow without additional mass lesion or abnormality. The remaining gastric mucosa is dusky tan-pink to tan red

[page 3 of 3]
with normal rugal folds and the wall averages 0.8 cm. Several rubbery tan-pink-red polyps measuring up to 0.6 cm are identified, the largest within 2 cm of the proximal margin (see block 1). The duodenal mucosa is unremarkable tan-pink with regular folds and the wall averages 0.5 cm. A few rubbery tan-white to tan-pink tissues in keeping with lymph nodes measuring up to 1.3 cm are recovered from the adipose tissue adjacent to the portion of pancreas (see blocks 17 and 18). Several additional presumptive lymph nodes are recovered from the greater and lesser curvature of the gastric tissue. A portion of the tumor and a portion of normal gastric mucosa are submitted for tissue procurement as requested.

Summary: 1 - perpendicular sections proximal margin, 2 - perpendicular sections distal margin, 3 through 5 - tumor to closest inked free radial serosal surface and common bile duct margin (points of continuity inked red and black), 6 - tumor to uncinate margin, 7 - tumor to neck margin, 8 and 9 - random pancreatic, 10 - duodenal papilla, 11 and 12 - additional sections of tumor to inked free radial serosal surface, 13 - tumor to normal gastric mucosa, 14 and 15 - gastric mucosa including remaining polyps, 16 - random duodenum, 17 - 3 lymph nodes in fat adjacent to pancreas, 18 - one bisected lymph node from fat adjacent to pancreas, 19 - 3 lymph nodes lesser curvature, Greater curvature lymph nodes: 20 - 6 lymph nodes, 21 - 3 lymph nodes, 22 through 24 - 1 bisected lymph node per cassette

HPA Discrepancy		
True Malignancy History		

10/26/12

Source: NCI Genomic Data Commons file 87b80140-217c-41c8-b187-c6440b3a6470 (TCGA-EQ-A4SO.6867386B-4C62-4442-950D-6E6E8EC3FBCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).